Somatic mutation profile of cancer-model specimen HCM-BROD-0924-C34-85A (3D Organoid, passage 6; aliquot HCM-BROD-0924-C34-85A-01D-A88G-36), derived from the metastatic tumor of HCMI case HCM-BROD-0924-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Small cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: GX; Age at diagnosis: 55.3 years (20,207 days).
Specimen HCM-BROD-0924-C34-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cf2f7436-3ab5-43f9-b0a5-efe83c07b32c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0924-C34-10A (Blood Derived Normal), aliquot HCM-BROD-0924-C34-10A-01D-A88G-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b1886166-00ec-4a25-bcf0-348d531063d5

The open-access MAF lists 577 somatic variants for this specimen: 432 protein-altering or splice-affecting, 114 silent, 31 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 366, Silent 114, Nonsense Mutation 33, Intron 20, Frame Shift Del 16, Splice Region 6, RNA 5, Splice Site 5, Frame Shift Ins 4, 3'UTR 4, 5'UTR 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.861G>C p.E287D | Missense Mutation (SNP) | VAF 135/135 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1555284956, CS011567, CS143241, COSV57331141, COSV99922896; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.824G>T p.C275F | Missense Mutation (SNP) | VAF 332/333 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs863224451, CM076568, CM951234, COSV52661919, COSV52663595, COSV52675710, COSV52772708; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCG8 | c.451G>A p.V151M | Missense Mutation (SNP) | VAF 176/353 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200631750, COSV55393393; called by muse, mutect2, varscan2
- ADCY1 | c.834G>T p.E278D | Missense Mutation (SNP) | VAF 278/279 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV52043563; called by muse, mutect2, varscan2
- ALLC | c.533G>T p.R178I | Missense Mutation (SNP) | VAF 135/264 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1422472520; called by muse, mutect2, varscan2
- AMER3 | c.1844C>G p.S615C | Missense Mutation (SNP) | VAF 223/466 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.308); catalogued as COSV58469904; called by muse, mutect2, varscan2
- ANKRD27 | c.1184C>T p.S395L | Missense Mutation (SNP) | VAF 79/346 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.553); catalogued as rs201398434, COSV60131683; called by muse, mutect2, varscan2
- ATP10D | c.3178G>A p.D1060N | Missense Mutation (SNP) | VAF 134/354 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56706494; called by muse, varscan2
- ATP8B2 | c.2542G>A p.G848R (on ENST00000672630; = p.G815R on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 126/367 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100528260; called by muse, mutect2, varscan2
- BEST3 | c.1498G>T p.V500L | Missense Mutation (SNP) | VAF 361/361 reads (100%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as rs746039339; called by muse, mutect2, varscan2
- BRINP3 | c.2271G>T p.M757I | Missense Mutation (SNP) | VAF 249/371 reads (67%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV66517513, COSV66523773; called by muse, mutect2, varscan2
- C10orf71 | c.3326G>A p.R1109Q | Missense Mutation (SNP) | VAF 662/662 reads (100%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1263573668; called by muse, mutect2, varscan2
- C6orf58 | c.622T>C p.W208R | Missense Mutation (SNP) | VAF 70/390 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs900653896, COSV100314831; called by muse, mutect2, varscan2
- C8B | c.800G>T p.G267V | Missense Mutation (SNP) | VAF 210/210 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs770553711; called by muse, mutect2, varscan2
- CARMIL2 | c.1919G>A p.R640Q | Missense Mutation (SNP) | VAF 134/135 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1275821153, COSV58023417; called by mutect2, varscan2
- CD22 | c.1430G>A p.W477* | Nonsense Mutation (SNP) | VAF 208/664 reads (31%) | catalogued as COSV99323097; called by muse, mutect2, varscan2
- CDH10 | c.246A>T p.Q82H | Missense Mutation (SNP) | VAF 100/281 reads (36%) | SIFT tolerated (0.59); PolyPhen benign (0.069); catalogued as COSV100051277; called by muse, mutect2, varscan2
- CDX4 | c.64G>T p.G22W | Missense Mutation (SNP) | VAF 250/252 reads (99%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); catalogued as rs1243376766, COSV65171420; called by muse, mutect2, varscan2
- CHST7 | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 287/287 reads (100%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.87); catalogued as COSV52099866; called by muse, mutect2, varscan2
- CLSTN2 | c.1915G>A p.G639S | Missense Mutation (SNP) | VAF 33/890 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.514); catalogued as COSV71720982; called by muse, mutect2
- COL12A1 | c.5593G>T p.D1865Y | Missense Mutation (SNP) | VAF 294/473 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100485852; called by muse, mutect2, varscan2
- COL22A1 | c.2231G>T p.G744V | Missense Mutation (SNP) | VAF 393/1136 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57347010; called by muse, mutect2
- COLEC12 | c.1771C>A p.P591T | Missense Mutation (SNP) | VAF 182/424 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as rs1381788031; called by muse, mutect2
- CPT1C | c.2105A>G p.Y702C | Missense Mutation (SNP) | VAF 256/415 reads (62%) | SIFT tolerated (0.3); PolyPhen benign (0.099); catalogued as rs1161252718, COSV54918536; called by muse, mutect2, varscan2
- CSMD1 | c.2239G>C p.V747L (on ENST00000520002; = p.V746L on NM_033225.6) | Missense Mutation (SNP) | VAF 143/263 reads (54%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as rs1563354503, COSV59351960; called by muse, mutect2, varscan2
- CSMD3 | c.3731C>T p.S1244F (on ENST00000297405 / NM_001363185.1; = p.S1140F on NM_052900.3) | Missense Mutation (SNP) | VAF 55/365 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs1423850872, COSV52236574; called by muse, mutect2, varscan2
- CSRNP3 | c.301G>T p.V101L | Missense Mutation (SNP) | VAF 225/485 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.349); catalogued as COSV58775487; called by muse, mutect2, varscan2
- CST4 | c.205C>A p.Q69K | Missense Mutation (SNP) | VAF 124/332 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as rs1405789365, COSV54149623; called by muse, mutect2, varscan2
- CUBN | c.8501C>T p.T2834M | Missense Mutation (SNP) | VAF 619/774 reads (80%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.628); catalogued as rs144422027, COSV100912418; called by muse, varscan2
- DBNDD2 | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 462/696 reads (66%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.001); catalogued as rs753728418; called by muse, mutect2, varscan2
- DCANP1 | c.614C>A p.S205* | Nonsense Mutation (SNP) | VAF 154/154 reads (100%) | catalogued as COSV72345937; called by muse, mutect2, varscan2
- DES | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 192/401 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs62636490, CM070888, CM136433, COSV64660164; ClinVar: not provided; called by muse, mutect2, varscan2
- DSG1 | c.1241C>A p.T414K | Missense Mutation (SNP) | VAF 90/201 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1225279735; called by muse, mutect2, varscan2
- DYRK3 | c.1312C>T p.R438C | Missense Mutation (SNP) | VAF 86/674 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782578729; called by muse, mutect2, varscan2
- EHBP1L1 | c.2654G>A p.G885E | Missense Mutation (SNP) | VAF 154/532 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV100499961; called by muse, mutect2, varscan2
- ELOA2 | c.1888C>A p.R630S | Missense Mutation (SNP) | VAF 162/162 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.362); catalogued as rs772554622, COSV55305200; called by mutect2, varscan2
- EN1 | c.924del p.A309Rfs*144 | Frame Shift Del (DEL) | VAF 139/362 reads (38%) | catalogued as COSV54631577; called by mutect2, pindel, varscan2
- EPB41L3 | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 242/483 reads (50%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.695); catalogued as rs376734530; called by muse, mutect2, varscan2
- EPHA3 | c.986C>A p.P329Q | Missense Mutation (SNP) | VAF 248/396 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100344880; called by muse, mutect2, varscan2
- ERICH4 | c.319C>A p.Q107K | Missense Mutation (SNP) | VAF 229/432 reads (53%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV55727288; called by muse, mutect2, varscan2
- ERICH6 | c.973A>G p.I325V | Missense Mutation (SNP) | VAF 321/843 reads (38%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.991); catalogued as rs1441992630; called by muse, mutect2, varscan2
- EYS | c.2647G>C p.E883Q | Missense Mutation (SNP) | VAF 77/224 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV65564226; called by muse, mutect2, varscan2
- FAM135B | c.1876G>T p.G626W | Missense Mutation (SNP) | VAF 457/1157 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV99417390; called by muse, mutect2, varscan2
- FAM172A | c.818A>G p.Y273C | Missense Mutation (SNP) | VAF 81/82 reads (99%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as rs758510194; called by muse, mutect2, varscan2
- FAM83C | c.1280C>T p.P427L | Missense Mutation (SNP) | VAF 426/646 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.666); catalogued as rs753747505; called by muse, mutect2, varscan2
- FCRL3 | c.656G>T p.R219M | Missense Mutation (SNP) | VAF 218/644 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs575879706, COSV63840625, COSV63844510; called by muse, mutect2, varscan2
- FCRL5 | c.2832T>A p.H944Q | Missense Mutation (SNP) | VAF 162/506 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.073); catalogued as COSV62515076; called by muse, mutect2, varscan2
- FLNC | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 577/578 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs747837157; called by muse, mutect2, varscan2
- FSIP2 | c.7114C>A p.Q2372K | Missense Mutation (SNP) | VAF 105/213 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.095); catalogued as rs752607678; called by muse, mutect2, varscan2
- FSIP2 | c.7115A>G p.Q2372R | Missense Mutation (SNP) | VAF 104/210 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.151); catalogued as rs755961306; called by muse, mutect2, varscan2
- GABRG2 | c.1350C>G p.D450E (on ENST00000361925 / NM_001375343.1; = p.D410E on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 196/196 reads (100%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.997); catalogued as COSV62715396; called by muse, mutect2, varscan2
- GIMAP1 | c.11G>C p.R4T | Missense Mutation (SNP) | VAF 385/385 reads (100%) | SIFT deleterious (0.05); PolyPhen benign (0.3); catalogued as COSV56189722, COSV56190219; called by muse, mutect2, varscan2
- GKN1 | c.430G>T p.G144W | Missense Mutation (SNP) | VAF 107/244 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761022678, COSV100933534; called by muse, mutect2, varscan2
- GLI3 | c.3652G>T p.E1218* | Nonsense Mutation (SNP) | VAF 548/548 reads (100%) | catalogued as COSV67895667; called by muse, mutect2, varscan2
- GPR12 | c.26T>C p.L9S | Missense Mutation (SNP) | VAF 350/350 reads (100%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0); catalogued as rs773376242; called by muse, mutect2, varscan2
- HDAC4 | c.2779G>T p.V927L | Missense Mutation (SNP) | VAF 153/296 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.584); catalogued as rs1272371710, COSV100612771; called by muse, mutect2, varscan2
- HHLA1 | c.532+1G>A p.X178_splice | Splice Site (SNP) | VAF 270/490 reads (55%) | catalogued as rs139995559; called by muse, mutect2, varscan2
- HMGCLL1 | c.720G>T p.M240I | Missense Mutation (SNP) | VAF 99/448 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as COSV99231326; called by muse, mutect2, varscan2
- HNF1A | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 452/452 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CM064311; called by muse, mutect2, varscan2
- IFI16 | c.1912C>T p.R638C (on ENST00000295809 / NM_001364867.2; = p.R582C on NM_005531.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 291/489 reads (60%) | SIFT tolerated (0.13); PolyPhen benign (0.085); catalogued as rs201148574; called by muse, mutect2, varscan2
- IGHM | c.967G>T p.G323W | Missense Mutation (SNP) | VAF 123/391 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs781869458; called by muse, mutect2, varscan2
- IGHV3-23 | c.6G>T p.E2D | Missense Mutation (SNP) | VAF 47/277 reads (17%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.015); catalogued as rs192001086; called by muse, varscan2
- IGHV3-53 | c.59A>G p.E20G | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as rs782505685; called by muse, mutect2, varscan2
- IGKV1-9 | c.157A>G p.S53G | Missense Mutation (SNP) | VAF 242/481 reads (50%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as rs534361310; called by muse, mutect2
- IL1RL1 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 93/185 reads (50%) | SIFT tolerated (0.63); PolyPhen benign (0.159); catalogued as rs1383762901; called by muse, mutect2, varscan2
- IL36A | c.333G>C p.Q111H | Missense Mutation (SNP) | VAF 236/428 reads (55%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.799); catalogued as COSV99382135; called by muse, mutect2, varscan2
- INKA1 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 243/243 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377010190; called by muse, mutect2, varscan2
- KCNV1 | c.186C>A p.H62Q | Missense Mutation (SNP) | VAF 491/1294 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.042); catalogued as rs977778850; called by muse, mutect2, varscan2
- KIF26B | c.2125C>G p.L709V | Missense Mutation (SNP) | VAF 193/611 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63642398; called by muse, mutect2, varscan2
- KLHL5 | c.2143G>T p.G715W | Missense Mutation (SNP) | VAF 201/201 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54679234; called by muse, mutect2, varscan2
- KREMEN1 | c.601G>A p.D201N (on ENST00000407188; = p.D203N on NM_032045.5) | Missense Mutation (SNP) | VAF 131/240 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs775655154; called by muse, mutect2, varscan2
- KRTAP13-2 | c.341C>T p.S114L | Missense Mutation (SNP) | VAF 435/437 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as rs777101437, COSV67761991; called by muse, mutect2, varscan2
- LGI3 | c.799C>T p.R267W | Missense Mutation (SNP) | VAF 93/196 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.787); catalogued as rs560898710; called by muse, mutect2, varscan2
- LHX8 | c.775del p.A259Qfs*6 | Frame Shift Del (DEL) | VAF 278/387 reads (72%) | catalogued as COSV53955742; called by mutect2, pindel, varscan2
- LPA | c.4177G>A p.G1393R | Missense Mutation (SNP) | VAF 160/886 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM011398; called by muse, mutect2
- LPA | c.3044C>T p.T1015I | Missense Mutation (SNP) | VAF 363/749 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.222); catalogued as rs1027477900, COSV60304471; called by muse, mutect2, varscan2
- LRP1B | c.7453G>T p.G2485W | Missense Mutation (SNP) | VAF 111/223 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67279511; called by muse, mutect2, varscan2
- MBD1 | c.1556C>T p.P519L (on ENST00000269468 / NM_001323950.1; = p.P463L on NM_015844.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 191/373 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.584); catalogued as COSV54005719; called by muse, mutect2, varscan2
- MBOAT2 | c.1352G>T p.C451F | Missense Mutation (SNP) | VAF 61/133 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs1304961489; called by muse, mutect2, varscan2
- MOXD1 | c.886C>A p.P296T | Missense Mutation (SNP) | VAF 197/411 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.071); catalogued as COSV60944233; called by muse, mutect2, varscan2
- MSL1 | c.1426C>T p.P476S (on ENST00000398532 / NM_001365919.1; = p.P213S on NM_001012241.2) | Missense Mutation (SNP) | VAF 87/208 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1555547967; called by muse, mutect2, varscan2
- MYH7 | c.775G>T p.A259S | Missense Mutation (SNP) | VAF 143/457 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.019); catalogued as COSV62523131; called by muse, mutect2, varscan2
- MYO16 | c.4661C>G p.A1554G | Missense Mutation (SNP) | VAF 134/134 reads (100%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.018); catalogued as rs769347635; called by muse, mutect2, varscan2
- MYO7B | c.3308G>T p.R1103L | Missense Mutation (SNP) | VAF 101/247 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs1228993592; called by muse, mutect2
- NBAS | c.3778A>T p.T1260S | Missense Mutation (SNP) | VAF 131/311 reads (42%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV55739441; called by muse, mutect2, varscan2
- NCAM2 | c.1383+1del | Frame Shift Del (DEL) | VAF 56/79 reads (71%) | catalogued as COSV99524627; called by mutect2, pindel, varscan2
- NCR1 | c.34G>A p.G12R | Missense Mutation (SNP) | VAF 329/1075 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.673); catalogued as rs1345515426, COSV52558142; called by muse, mutect2, varscan2
- NEB | c.5854A>G p.M1952V | Missense Mutation (SNP) | VAF 213/412 reads (52%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.841); catalogued as rs200649387; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NECTIN3 | c.1309G>T p.D437Y | Missense Mutation (SNP) | VAF 220/342 reads (64%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.265); catalogued as COSV72202777; called by mutect2, varscan2
- NIM1K | c.1261C>T p.R421C | Missense Mutation (SNP) | VAF 123/381 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.543); catalogued as rs761768735; called by muse, mutect2, varscan2
- NKD2 | c.1000C>T p.P334S | Missense Mutation (SNP) | VAF 318/1002 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1222092266, COSV56894435; called by muse, mutect2, varscan2
- NUGGC | c.854G>A p.G285E | Missense Mutation (SNP) | VAF 164/358 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1330392679; called by muse, mutect2, varscan2
- OR2T12 | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 45/417 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.075); catalogued as rs764836025, COSV58776972; called by muse, mutect2, varscan2
- OR4A16 | c.151C>A p.P51T | Missense Mutation (SNP) | VAF 182/590 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.558); catalogued as COSV59043930; called by muse, mutect2, varscan2
- OR4N2 | c.675A>G p.I225M | Missense Mutation (SNP) | VAF 142/887 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as rs145980684; called by muse, mutect2, varscan2
- OR5H6 | c.874C>G p.L292V (on ENST00000642105; = p.L276V on NM_001005479.2) | Missense Mutation (SNP) | VAF 148/481 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.116); catalogued as rs1427509855; called by muse, mutect2, varscan2
- OR7G2 | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 405/407 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV59688383; called by muse, mutect2, varscan2
- OR8K1 | c.774T>A p.Y258* | Nonsense Mutation (SNP) | VAF 184/584 reads (32%) | catalogued as COSV54402998; called by muse, mutect2, varscan2
- PCDHA1 | c.703del p.V235Lfs*18 | Frame Shift Del (DEL) | VAF 175/181 reads (97%) | catalogued as COSV100974610; called by mutect2, pindel*, varscan2
- PER2 | c.3349A>G p.M1117V | Missense Mutation (SNP) | VAF 149/315 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV54525671; called by muse, mutect2, varscan2
- PKHD1L1 | c.4921G>T p.G1641C | Missense Mutation (SNP) | VAF 456/820 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101005554; called by muse, mutect2, varscan2
- PLCL2 | c.905G>T p.G302V (on ENST00000615277 / NM_001144382.2; = p.G176V on NM_015184.5) | Missense Mutation (SNP) | VAF 110/110 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as COSV101197090; called by muse, mutect2, varscan2
- PPIL3 | c.201G>T p.W67C (on ENST00000392283 / NM_130906.3; = p.W71C on NM_032472.4) | Missense Mutation (SNP) | VAF 71/213 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as COSV99626789; called by muse, mutect2, varscan2
- PPP1R13L | c.1042C>A p.P348T | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); catalogued as rs1169667848; called by muse, mutect2
- PRDM9 | c.1676G>C p.R559P | Missense Mutation (SNP) | VAF 400/595 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV57010925, COSV99690866; called by muse, mutect2, varscan2
- PRR23A | c.477C>A p.D159E | Missense Mutation (SNP) | VAF 314/796 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV67214722; called by muse, mutect2, varscan2
- RAI14 | c.346G>T p.D116Y | Missense Mutation (SNP) | VAF 115/488 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54295361; called by muse, mutect2, varscan2
- RGS6 | c.1370del p.X457_splice | Splice Site (DEL) | VAF 338/653 reads (52%) | catalogued as CS151753; called by mutect2, pindel, varscan2
- RPS6KA6 | c.1324C>T p.R442* | Nonsense Mutation (SNP) | VAF 100/276 reads (36%) | catalogued as COSV53116827, COSV53121021; called by muse, mutect2, varscan2
- RYR2 | c.14221G>T p.A4741S | Missense Mutation (SNP) | VAF 101/405 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100767825, COSV63684127; called by muse, mutect2, varscan2
- S100A8 | c.207G>T p.Q69H | Missense Mutation (SNP) | VAF 185/635 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV64198007; called by muse, mutect2, varscan2
- SALL3 | c.1906C>G p.L636V | Missense Mutation (SNP) | VAF 319/669 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.471); catalogued as rs1273733851; called by muse, mutect2, varscan2
- SCARA3 | c.1213A>G p.I405V | Missense Mutation (SNP) | VAF 199/444 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs756392656; called by muse, mutect2, varscan2
- SEC14L3 | c.1202A>G p.*401Wext*13 | Nonstop Mutation (SNP) | VAF 94/217 reads (43%) | catalogued as rs980937855; called by muse, mutect2, varscan2
- SH3KBP1 | c.626A>T p.K209I | Missense Mutation (SNP) | VAF 241/241 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as COSV101115200; called by muse, mutect2, varscan2
- SHROOM3 | c.1192C>T p.R398C | Missense Mutation (SNP) | VAF 383/385 reads (99%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs754893564, COSV99934704; called by muse, mutect2, varscan2
- SIPA1L2 | c.1267C>T p.R423W | Missense Mutation (SNP) | VAF 160/517 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs780723482; called by muse, mutect2, varscan2
- SLC26A7 | c.1630G>T p.E544* | Nonsense Mutation (SNP) | VAF 66/216 reads (31%) | catalogued as COSV99402772; called by mutect2, varscan2
- SLCO1C1 | c.1488C>G p.I496M | Missense Mutation (SNP) | VAF 109/253 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.4); catalogued as COSV56872209; called by muse, mutect2, varscan2
- SMIM17 | c.126G>T p.E42D | Missense Mutation (SNP) | VAF 168/532 reads (32%) | SIFT tolerated, low confidence (0.24); PolyPhen probably damaging (0.955); catalogued as COSV74090495; called by muse, varscan2
- SNTG1 | c.427C>A p.P143T | Missense Mutation (SNP) | VAF 69/207 reads (33%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.987); catalogued as rs150801015; called by muse, mutect2, varscan2
- SOX17 | c.1046G>C p.S349T | Missense Mutation (SNP) | VAF 337/685 reads (49%) | SIFT tolerated (0.44); PolyPhen benign (0.026); catalogued as COSV52028042; called by muse, mutect2, varscan2
- SPATA16 | c.560A>G p.Y187C | Missense Mutation (SNP) | VAF 285/770 reads (37%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs1442014024, COSV63532469; called by muse, mutect2, varscan2
- SPEF2 | c.1643C>A p.A548E | Missense Mutation (SNP) | VAF 269/412 reads (65%) | SIFT tolerated (0.52); PolyPhen benign (0.048); catalogued as rs766203832; called by muse, mutect2, varscan2
- SRRM4 | c.1433G>T p.R478L | Missense Mutation (SNP) | VAF 143/362 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.025); catalogued as COSV57412746, COSV99939730; called by muse, mutect2, varscan2
- STK36 | c.1285C>G p.P429A | Missense Mutation (SNP) | VAF 147/353 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.847); catalogued as rs746425399; called by muse, mutect2, varscan2
- STYXL2 | c.2954C>A p.S985* | Nonsense Mutation (SNP) | VAF 152/430 reads (35%) | catalogued as rs1310801259, COSV54809312; called by muse, mutect2, varscan2
- SYNE1 | c.1350+1G>C p.X450_splice (on ENST00000367255 / NM_182961.4; = p.X457_splice on NM_033071.3) | Splice Site (SNP) | VAF 114/463 reads (25%) | catalogued as COSV99562633; called by muse, mutect2, varscan2
- TAAR1 | c.402G>C p.K134N | Missense Mutation (SNP) | VAF 275/566 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.2); catalogued as COSV51588383; called by muse, mutect2, varscan2
- TBX4 | c.1498G>T p.G500W | Missense Mutation (SNP) | VAF 472/472 reads (100%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.038); catalogued as COSV53606774; called by muse, mutect2, varscan2
- TCP10L2 | c.19G>C p.E7Q | Missense Mutation (SNP) | VAF 271/595 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.859); catalogued as COSV52087505; called by muse, mutect2, varscan2
- TDRD12 | c.653T>A p.L218H | Missense Mutation (SNP) | VAF 87/279 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.62); catalogued as COSV101416366; called by muse, mutect2, varscan2
- TNS3 | c.4068G>C p.Q1356H | Missense Mutation (SNP) | VAF 291/292 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.093); catalogued as COSV100236382; called by muse, mutect2, varscan2
- TRIM54 | c.194G>T p.R65L | Missense Mutation (SNP) | VAF 170/319 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV99940952; called by muse, mutect2, varscan2
- TTLL9 | c.89A>G p.H30R | Missense Mutation (SNP) | VAF 335/519 reads (65%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as rs749750761; called by muse, mutect2, varscan2
- TTN | c.21017C>A p.P7006H (on ENST00000591111; = p.P6079H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 93/218 reads (43%) | PolyPhen probably damaging (0.992); catalogued as COSV60195786; called by muse, mutect2, varscan2
- USP33 | c.842A>G p.D281G | Missense Mutation (SNP) | VAF 167/313 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778402624; called by muse, mutect2, varscan2
- VAX1 | c.469_471del p.K157del | In Frame Del (DEL) | VAF 158/172 reads (92%) | catalogued as rs1199626010; called by pindel, varscan2
- VEPH1 | c.217G>T p.E73* | Nonsense Mutation (SNP) | VAF 158/975 reads (16%) | catalogued as COSV62882851; called by muse, mutect2, varscan2
- VTCN1 | c.226G>A p.V76I | Missense Mutation (SNP) | VAF 195/434 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as rs1396710632; called by muse, mutect2, varscan2
- VWCE | c.2138A>T p.Q713L | Missense Mutation (SNP) | VAF 130/377 reads (34%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as rs1376524587; called by mutect2, varscan2
- VWDE | c.2626G>T p.E876* | Nonsense Mutation (SNP) | VAF 327/328 reads (100%) | catalogued as COSV51726734; called by muse, mutect2, varscan2
- ZNF675 | c.1136G>T p.R379L | Missense Mutation (SNP) | VAF 337/511 reads (66%) | SIFT tolerated (0.67); PolyPhen benign (0.03); catalogued as COSV100705028; called by muse, mutect2, varscan2
- A4GNT | c.224C>A p.A75D | Missense Mutation (SNP) | VAF 644/809 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACSM4 | c.1708A>G p.N570D | Missense Mutation (SNP) | VAF 139/140 reads (99%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- ADAM18 | c.733A>G p.T245A | Missense Mutation (SNP) | VAF 217/399 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- ADAM33 | c.1782C>A p.D594E | Missense Mutation (SNP) | VAF 466/704 reads (66%) | SIFT tolerated (0.56); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- ADCY8 | c.241C>G p.P81A | Missense Mutation (SNP) | VAF 569/1434 reads (40%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ADGRF1 | c.833G>A p.G278D | Missense Mutation (SNP) | VAF 166/331 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AFF3 | c.2854C>G p.P952A | Missense Mutation (SNP) | VAF 184/360 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- AGPAT3 | c.49G>T p.V17F | Missense Mutation (SNP) | VAF 361/361 reads (100%) | SIFT tolerated (0.88); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKS4B | c.158G>A p.S53N | Missense Mutation (SNP) | VAF 97/190 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- ANO7 | c.1406C>T p.A469V (on ENST00000274979; = p.A415V on NM_001370694.2) | Missense Mutation (SNP) | VAF 269/536 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- APOB | c.7528G>T p.A2510S | Missense Mutation (SNP) | VAF 199/394 reads (51%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- ARHGEF26 | c.2344_2357delinsA p.G782Kfs*6 | Frame Shift Del (DEL) | VAF 222/965 reads (23%) | called by pindel, varscan2*
- ASAP3 | c.1946G>T p.G649V | Missense Mutation (SNP) | VAF 110/253 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.369); called by muse, mutect2, varscan2
- ASPM | c.3485G>T p.C1162F | Missense Mutation (SNP) | VAF 124/394 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- ATP12A | c.304C>A p.P102T | Missense Mutation (SNP) | VAF 625/626 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- ATP8B3 | c.62C>A p.A21D | Missense Mutation (SNP) | VAF 284/842 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- AXDND1 | c.2865T>A p.H955Q | Missense Mutation (SNP) | VAF 76/252 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- BCAS3 | c.1911G>T p.K637N (on ENST00000390652 / NM_001353144.2; = p.K622N on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 400/400 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BRCA2 | c.2688T>G p.N896K | Missense Mutation (SNP) | VAF 77/259 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BRD1 | c.1601G>T p.R534L | Missense Mutation (SNP) | VAF 246/461 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BSN | c.9601G>A p.G3201S | Missense Mutation (SNP) | VAF 255/255 reads (100%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- C8B | c.799G>T p.G267C | Missense Mutation (SNP) | VAF 199/199 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.322); called by mutect2, varscan2
- C8orf76 | c.932T>C p.L311S | Missense Mutation (SNP) | VAF 272/728 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- CACNA1C | c.1688T>C p.L563P | Missense Mutation (SNP) | VAF 186/347 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CACNA1S | c.5555G>T p.G1852V | Missense Mutation (SNP) | VAF 216/741 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CCDC168 | c.7406C>A p.S2469* | Nonsense Mutation (SNP) | VAF 149/149 reads (100%) | called by muse, mutect2, varscan2
- CCDC171 | c.3511A>C p.N1171H | Missense Mutation (SNP) | VAF 115/434 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CCDC47 | c.1093+1G>A p.X365_splice | Splice Site (SNP) | VAF 54/127 reads (43%) | called by muse, mutect2, varscan2
- CDH22 | c.2245G>T p.D749Y | Missense Mutation (SNP) | VAF 449/729 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- CDKL2 | c.1136A>G p.H379R | Missense Mutation (SNP) | VAF 395/395 reads (100%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- CENPVL3 | c.451G>C p.G151R | Missense Mutation (SNP) | VAF 192/522 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CEP170 | c.1510A>G p.I504V | Missense Mutation (SNP) | VAF 151/433 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- CERKL | c.526C>A p.Q176K | Missense Mutation (SNP) | VAF 76/194 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.206); called by mutect2, varscan2
- CHRNB3 | c.332G>T p.W111L | Missense Mutation (SNP) | VAF 112/274 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHST2 | c.1477A>G p.K493E | Missense Mutation (SNP) | VAF 186/922 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.034); called by muse, varscan2
- CLIP1 | c.3900G>T p.Q1300H (on ENST00000620786 / NM_001247997.1; = p.Q1289H on NM_002956.2) | Missense Mutation (SNP) | VAF 254/254 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- CMKLR1 | c.725C>G p.T242S (on ENST00000312143 / NM_001142344.2; = p.T240S on NM_004072.3) | Missense Mutation (SNP) | VAF 295/296 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- CNGA4 | c.387C>A p.Y129* | Nonsense Mutation (SNP) | VAF 419/420 reads (100%) | called by muse, mutect2, varscan2
- COL12A1 | c.8645G>T p.R2882I | Missense Mutation (SNP) | VAF 154/457 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- COL19A1 | c.1597A>G p.M533V | Missense Mutation (SNP) | VAF 125/420 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL22A1 | c.1951C>A p.Q651K | Missense Mutation (SNP) | VAF 291/882 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CPED1 | c.1747T>A p.L583M | Missense Mutation (SNP) | VAF 369/369 reads (100%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CPS1 | c.1288T>C p.S430P | Missense Mutation (SNP) | VAF 119/241 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CPXM1 | c.2159C>A p.P720Q | Missense Mutation (SNP) | VAF 136/456 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CRB1 | c.3146C>T p.S1049F | Missense Mutation (SNP) | VAF 363/553 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CREBZF | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 32/766 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2
- CSMD1 | c.3249G>T p.K1083N (on ENST00000520002; = p.K1082N on NM_033225.6) | Missense Mutation (SNP) | VAF 172/387 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- CSMD3 | c.6257G>A p.G2086D (on ENST00000297405 / NM_001363185.1; = p.G1982D on NM_052900.3) | Missense Mutation (SNP) | VAF 160/438 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- CSRNP3 | c.1168G>T p.G390* | Nonsense Mutation (SNP) | VAF 182/398 reads (46%) | called by muse, mutect2, varscan2
- CTNND2 | c.2387G>T p.G796V | Missense Mutation (SNP) | VAF 415/659 reads (63%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- CXorf21 | c.532del p.Q178Kfs*13 | Frame Shift Del (DEL) | VAF 240/332 reads (72%) | called by mutect2, pindel, varscan2
- CYP1A2 | c.1531C>A p.L511M | Missense Mutation (SNP) | VAF 129/283 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- CYP27A1 | c.1135G>T p.D379Y | Missense Mutation (SNP) | VAF 194/422 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- DDX53 | c.739C>G p.P247A | Missense Mutation (SNP) | VAF 213/213 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DEUP1 | c.286C>A p.L96I | Missense Mutation (SNP) | VAF 69/300 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DMXL2 | c.7474T>C p.S2492P | Missense Mutation (SNP) | VAF 58/148 reads (39%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.986); called by muse, varscan2
- DMXL2 | c.421G>A p.D141N | Missense Mutation (SNP) | VAF 96/210 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.264); called by muse, varscan2
- DNAH10 | c.13298C>A p.A4433E (on ENST00000409039; = p.A4372E on NM_207437.3) | Missense Mutation (SNP) | VAF 327/327 reads (100%) | SIFT tolerated (0.18); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- DNAH9 | c.1235G>A p.R412K | Missense Mutation (SNP) | VAF 267/267 reads (100%) | SIFT tolerated (0.45); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- DNAJC13 | c.5803A>G p.R1935G | Missense Mutation (SNP) | VAF 80/258 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DOCK2 | c.2703G>T p.A901= | Splice Region (SNP) | VAF 114/114 reads (100%) | called by muse, mutect2, varscan2
- DPYD | c.442G>T p.G148* | Nonsense Mutation (SNP) | VAF 284/284 reads (100%) | called by muse, mutect2, varscan2
- DRAXIN | c.575C>A p.T192N | Missense Mutation (SNP) | VAF 512/513 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- DRP2 | c.2248G>C p.D750H | Missense Mutation (SNP) | VAF 298/298 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DYNC2H1 | c.11213A>T p.Q3738L | Missense Mutation (SNP) | VAF 353/478 reads (74%) | SIFT tolerated (0.08); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ELSPBP1 | c.586T>A p.C196S | Missense Mutation (SNP) | VAF 147/147 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EML4 | c.290G>T p.S97I | Missense Mutation (SNP) | VAF 113/262 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- EMX1 | c.255C>G p.Y85* | Nonsense Mutation (SNP) | VAF 282/569 reads (50%) | called by muse, mutect2, varscan2
- EP400 | c.4348C>G p.P1450A | Missense Mutation (SNP) | VAF 484/484 reads (100%) | SIFT tolerated (0.05); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- EPHA6 | c.587T>A p.V196E | Missense Mutation (SNP) | VAF 264/429 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EPHA6 | c.2542A>C p.M848L (on ENST00000389672 / NM_001080448.3; = p.M240L on NM_173655.4) | Missense Mutation (SNP) | VAF 152/460 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); called by mutect2, varscan2
- EXOC5 | c.559A>T p.S187C | Missense Mutation (SNP) | VAF 126/190 reads (66%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- EXOG | c.322G>T p.D108Y | Missense Mutation (SNP) | VAF 123/123 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- EZHIP | c.209C>G p.A70G | Missense Mutation (SNP) | VAF 258/259 reads (100%) | SIFT tolerated (0.24); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- F8 | c.3517A>T p.K1173* | Nonsense Mutation (SNP) | VAF 332/332 reads (100%) | called by muse, mutect2, varscan2
- FAM47A | c.844G>T p.G282C | Missense Mutation (SNP) | VAF 249/249 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- FARS2 | c.1051A>T p.K351* | Nonsense Mutation (SNP) | VAF 85/230 reads (37%) | called by muse, mutect2, varscan2
- FAT3 | c.455A>T p.N152I | Missense Mutation (SNP) | VAF 110/412 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FGF6 | c.260G>A p.R87K | Missense Mutation (SNP) | VAF 342/342 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FIGN | c.29C>T p.T10I | Missense Mutation (SNP) | VAF 115/264 reads (44%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- FLI1 | c.139A>G p.K47E | Missense Mutation (SNP) | VAF 183/767 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- FLI1 | c.957del p.R319Sfs*12 | Frame Shift Del (DEL) | VAF 206/867 reads (24%) | called by mutect2, pindel*, varscan2
- G6PC2 | c.737C>A p.P246H | Missense Mutation (SNP) | VAF 275/573 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- GLIS3 | c.104C>G p.S35C | Missense Mutation (SNP) | VAF 220/682 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- GLT6D1 | c.464G>T p.G155V | Missense Mutation (SNP) | VAF 411/412 reads (100%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.505); called by muse, mutect2, varscan2
- GLYATL2 | c.139G>T p.D47Y | Missense Mutation (SNP) | VAF 78/345 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPR19 | c.616T>A p.W206R | Missense Mutation (SNP) | VAF 343/343 reads (100%) | SIFT tolerated (0.57); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- GPR37L1 | c.985C>A p.Q329K | Missense Mutation (SNP) | VAF 226/720 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- GPRC6A | c.1397C>A p.A466D | Missense Mutation (SNP) | VAF 205/445 reads (46%) | SIFT tolerated (0.49); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- GPRIN3 | c.969G>T p.Q323H | Missense Mutation (SNP) | VAF 406/406 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRIK4 | c.2248G>A p.G750R | Missense Mutation (SNP) | VAF 115/515 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- H2AC1 | c.91A>T p.I31F | Missense Mutation (SNP) | VAF 381/382 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- HCN1 | c.1794T>A p.N598K | Missense Mutation (SNP) | VAF 113/343 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- HELZ2 | c.5796G>T p.R1932S (on ENST00000467148 / NM_001037335.2; = p.R1363S on NM_033405.3) | Missense Mutation (SNP) | VAF 493/735 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- HMCN1 | c.2596A>T p.I866F | Missense Mutation (SNP) | VAF 111/328 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- HPS4 | c.1600T>C p.S534P | Missense Mutation (SNP) | VAF 175/390 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGHM | c.966G>T p.K322N | Missense Mutation (SNP) | VAF 121/391 reads (31%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- IGHV3-23 | c.12del p.L5* | Frame Shift Del (DEL) | VAF 33/292 reads (11%) | called by pindel, varscan2
- IGHV3-64 | c.191G>T p.G64V | Missense Mutation (SNP) | VAF 308/437 reads (70%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- IGHV3-66 | c.59A>G p.E20G | Missense Mutation (SNP) | VAF 85/805 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- IGHV3OR15-7 | c.347A>G p.Y116C | Missense Mutation (SNP) | VAF 195/195 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGLON5 | c.179T>A p.V60E | Missense Mutation (SNP) | VAF 202/634 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITGAL | c.2308A>G p.N770D | Missense Mutation (SNP) | VAF 155/328 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- KANK2 | c.787G>T p.E263* | Nonsense Mutation (SNP) | VAF 696/696 reads (100%) | called by muse, mutect2, varscan2
- KCNAB2 | c.623C>A p.T208N | Missense Mutation (SNP) | VAF 146/363 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- KCNF1 | c.945T>A p.Y315* | Nonsense Mutation (SNP) | VAF 302/579 reads (52%) | called by muse, mutect2, varscan2
- KCNK10 | c.1013C>A p.A338D | Missense Mutation (SNP) | VAF 254/388 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNK18 | c.139G>T p.G47C | Missense Mutation (SNP) | VAF 180/180 reads (100%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- KIAA1549L | c.3195G>T p.Q1065H (on ENST00000321505; = p.Q1362H on NM_012194.3) | Missense Mutation (SNP) | VAF 266/267 reads (100%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- KIF5B | c.701G>C p.G234A | Missense Mutation (SNP) | VAF 217/217 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIRREL2 | c.1501G>T p.G501C | Missense Mutation (SNP) | VAF 89/320 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- KIRREL3 | c.509G>T p.C170F | Missense Mutation (SNP) | VAF 550/768 reads (72%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- KIRREL3 | c.508T>A p.C170S | Missense Mutation (SNP) | VAF 549/766 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- KLHL11 | c.808G>C p.V270L | Missense Mutation (SNP) | VAF 146/285 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- KRT6A | c.1129A>G p.T377A | Missense Mutation (SNP) | VAF 55/390 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- KRT6B | c.1129A>G p.T377A | Missense Mutation (SNP) | VAF 80/178 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- KRTAP13-1 | c.35C>G p.S12C | Missense Mutation (SNP) | VAF 245/245 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- LACTB | c.744_771del p.F248Lfs*38 | Frame Shift Del (DEL) | VAF 142/160 reads (89%) | called by mutect2, pindel, varscan2
- LBX2 | c.217C>G p.P73A (on ENST00000377566 / NM_001282430.2; = p.P69A on NM_001009812.2) | Missense Mutation (SNP) | VAF 157/324 reads (48%) | SIFT tolerated (0.77); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LENG8 | c.284A>G p.Y95C | Missense Mutation (SNP) | VAF 356/556 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LEPR | c.1318G>T p.G440W | Missense Mutation (SNP) | VAF 203/203 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LGI2 | c.1582A>T p.S528C | Missense Mutation (SNP) | VAF 135/135 reads (100%) | SIFT tolerated (0.18); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LGI3 | c.800G>C p.R267P | Missense Mutation (SNP) | VAF 91/190 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- LILRB2 | c.1111A>G p.I371V | Missense Mutation (SNP) | VAF 259/842 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LINGO4 | c.1362G>T p.W454C | Missense Mutation (SNP) | VAF 270/853 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- LOXL2 | c.22C>T p.H8Y | Missense Mutation (SNP) | VAF 122/280 reads (44%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- LRRC2 | c.1015C>T p.H339Y | Missense Mutation (SNP) | VAF 99/99 reads (100%) | SIFT tolerated (0.88); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRC30 | c.484C>A p.L162I | Missense Mutation (SNP) | VAF 214/449 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- LRRK2 | c.1555G>T p.E519* | Nonsense Mutation (SNP) | VAF 166/166 reads (100%) | called by muse, mutect2, varscan2
- LRRTM4 | c.526G>T p.V176F | Missense Mutation (SNP) | VAF 124/281 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- LTBP1 | c.4502C>A p.A1501E (on ENST00000404816 / NM_206943.4; = p.A1175E on NM_000627.4) | Missense Mutation (SNP) | VAF 130/285 reads (46%) | SIFT tolerated (0.39); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- MAP1LC3B | c.240C>A p.F80L | Missense Mutation (SNP) | VAF 111/114 reads (97%) | SIFT deleterious (0.04); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- MARCKS | c.622G>T p.G208C | Missense Mutation (SNP) | VAF 557/561 reads (99%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- MAST1 | c.2005G>T p.E669* | Nonsense Mutation (SNP) | VAF 161/457 reads (35%) | called by muse, mutect2, varscan2
- MEX3D | c.1508G>C p.R503P | Missense Mutation (SNP) | VAF 522/523 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- MKI67 | c.4912G>T p.G1638W | Missense Mutation (SNP) | VAF 218/218 reads (100%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MPIG6B | c.469G>A p.G157R | Missense Mutation (SNP) | VAF 34/650 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.883); called by muse, mutect2
- MPPED2 | c.281C>G p.S94* | Nonsense Mutation (SNP) | VAF 122/283 reads (43%) | called by muse, mutect2, varscan2
- MRGPRX3 | c.416C>T p.S139L | Missense Mutation (SNP) | VAF 328/328 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MROH2B | c.4650A>T p.T1550= | Splice Region (SNP) | VAF 146/642 reads (23%) | called by muse, mutect2, varscan2
- MS4A13 | c.33C>A p.Y11* | Nonsense Mutation (SNP) | VAF 118/187 reads (63%) | called by muse, mutect2, varscan2
- MTTP | c.1401del p.E468Rfs*10 | Frame Shift Del (DEL) | VAF 322/444 reads (73%) | called by mutect2, pindel, varscan2
- MUC12 | c.3967T>C p.S1323P (on ENST00000379442; = p.S1180P on NM_001164462.1) | Missense Mutation (SNP) | VAF 649/1004 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- MUC12 | c.10343C>G p.P3448R (on ENST00000379442; = p.P3305R on NM_001164462.1) | Missense Mutation (SNP) | VAF 572/5472 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- MUC12 | c.11282C>G p.S3761C (on ENST00000379442; = p.S3618C on NM_001164462.1) | Missense Mutation (SNP) | VAF 474/4205 reads (11%) | SIFT deleterious (0.03); called by muse, varscan2
- MUC12 | c.13592C>G p.P4531R (on ENST00000379442; = p.P4388R on NM_001164462.1) | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); called by mutect2, varscan2
- MUC16 | c.33859A>C p.S11287R | Missense Mutation (SNP) | VAF 504/505 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- MUC16 | c.5539C>T p.L1847F | Missense Mutation (SNP) | VAF 529/529 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- MYBBP1A | c.1563G>C p.L521F | Missense Mutation (SNP) | VAF 253/253 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MYH7 | c.4344C>G p.N1448K | Missense Mutation (SNP) | VAF 156/498 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- MYOM1 | c.2780A>C p.K927T | Missense Mutation (SNP) | VAF 122/285 reads (43%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- NAALAD2 | c.1789T>A p.Y597N | Missense Mutation (SNP) | VAF 110/438 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- NBEAL1 | c.1838G>T p.G613V | Missense Mutation (SNP) | VAF 101/200 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- NCAM1 | c.569A>T p.E190V | Missense Mutation (SNP) | VAF 503/690 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NCLN | c.1297G>C p.G433R | Missense Mutation (SNP) | VAF 412/414 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- NDP | c.234G>T p.L78F | Missense Mutation (SNP) | VAF 294/294 reads (100%) | SIFT tolerated (0.06); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- NEK2 | c.433G>C p.A145P | Missense Mutation (SNP) | VAF 389/545 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- NES | c.3826C>A p.Q1276K | Missense Mutation (SNP) | VAF 474/726 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- NFASC | c.509C>T p.S170F (on ENST00000339876 / NM_001378329.1; = p.S164F on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 310/492 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- NIPAL1 | c.674T>C p.L225S | Missense Mutation (SNP) | VAF 290/458 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- NLGN4X | c.202G>T p.G68C | Missense Mutation (SNP) | VAF 212/212 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NLRP13 | c.2542A>T p.N848Y | Missense Mutation (SNP) | VAF 133/476 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- NLRP13 | c.1972A>G p.I658V | Missense Mutation (SNP) | VAF 469/686 reads (68%) | SIFT tolerated (0.13); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NOL4 | c.181G>T p.G61C | Missense Mutation (SNP) | VAF 228/473 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- NPBWR1 | c.881G>C p.S294T | Missense Mutation (SNP) | VAF 214/452 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- NTM | c.608C>A p.A203D | Missense Mutation (SNP) | VAF 377/535 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- NTRK3 | c.1112A>G p.Y371C | Missense Mutation (SNP) | VAF 780/781 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- NYX | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 14/330 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2
- OGDH | c.304G>T p.G102C | Missense Mutation (SNP) | VAF 366/599 reads (61%) | SIFT tolerated (0.08); PolyPhen benign (0.195); called by muse, mutect2, varscan2
- OPRK1 | c.500T>C p.L167S | Missense Mutation (SNP) | VAF 201/426 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR10G2 | c.388G>C p.A130P | Missense Mutation (SNP) | VAF 107/442 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- OR1G1 | c.439G>C p.A147P | Missense Mutation (SNP) | VAF 383/383 reads (100%) | SIFT tolerated (0.15); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- OR1I1 | c.83T>A p.F28Y | Missense Mutation (SNP) | VAF 613/614 reads (100%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- OR1J4 | c.641T>C p.I214T | Missense Mutation (SNP) | VAF 195/398 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- OR1S1 | c.853A>T p.K285* | Nonsense Mutation (SNP) | VAF 174/569 reads (31%) | called by mutect2, varscan2
- OR2AG2 | c.326G>A p.S109N | Missense Mutation (SNP) | VAF 153/312 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- OR2G3 | c.427C>A p.Q143K | Missense Mutation (SNP) | VAF 214/639 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR2J3 | c.295G>T p.G99C | Missense Mutation (SNP) | VAF 516/516 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- OR2J3 | c.296G>T p.G99V | Missense Mutation (SNP) | VAF 515/515 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- OR2T4 | c.151A>T p.R51* | Nonsense Mutation (SNP) | VAF 477/533 reads (89%) | called by muse, mutect2, varscan2
- OR8B3 | c.475C>A p.H159N | Missense Mutation (SNP) | VAF 417/700 reads (60%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- OR8B3 | c.379T>C p.C127R | Missense Mutation (SNP) | VAF 166/858 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- OR8B8 | c.374C>A p.A125D | Missense Mutation (SNP) | VAF 220/876 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OSBPL8 | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 71/170 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- OTOF | c.3698C>A p.P1233H (on ENST00000272371 / NM_194248.3; = p.P486H on NM_004802.4) | Missense Mutation (SNP) | VAF 191/405 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- OTOG | c.8749C>A p.P2917T | Missense Mutation (SNP) | VAF 16/413 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2
- P2RY10 | c.799A>T p.T267S | Missense Mutation (SNP) | VAF 209/209 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PAK2 | c.487G>T p.E163* | Nonsense Mutation (SNP) | VAF 446/581 reads (77%) | called by muse, mutect2, varscan2
- PAPOLB | c.1210G>T p.G404W | Missense Mutation (SNP) | VAF 325/326 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PAPPA2 | c.1910A>G p.N637S | Missense Mutation (SNP) | VAF 159/508 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- PARG | c.281A>T p.E94V | Missense Mutation (SNP) | VAF 239/239 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- PARP4 | c.3205C>A p.L1069M | Missense Mutation (SNP) | VAF 177/755 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.312); called by muse, mutect2
- PCDH11X | c.1231G>T p.V411L | Missense Mutation (SNP) | VAF 444/444 reads (100%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHA1 | c.1804G>T p.G602C | Missense Mutation (SNP) | VAF 172/172 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCSK2 | c.835G>A p.D279N | Missense Mutation (SNP) | VAF 201/675 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- PFN4 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 133/324 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- PKHD1 | c.10791T>A p.F3597L | Missense Mutation (SNP) | VAF 449/647 reads (69%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLAAT3 | c.450dup p.G151Wfs*45 | Frame Shift Ins (INS) | VAF 391/747 reads (52%) | called by mutect2, pindel, varscan2
- PLCH1 | c.3518A>G p.Q1173R (on ENST00000340059 / NM_001130960.2; = p.Q1165R on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 696/912 reads (76%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PLCH1 | c.2558T>C p.I853T (on ENST00000340059 / NM_001130960.2; = p.I865T on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 92/478 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.24); called by muse, varscan2
- PLCH1 | c.256G>A p.E86K (on ENST00000340059 / NM_001130960.2; = p.E98K on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 582/698 reads (83%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, varscan2
- PLCL1 | c.1608G>A p.M536I | Missense Mutation (SNP) | VAF 174/363 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- POLR3C | c.1432G>T p.G478C | Missense Mutation (SNP) | VAF 310/485 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- POTEC | c.1598T>C p.I533T | Missense Mutation (SNP) | VAF 87/199 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- POTEG | c.50C>G p.P17R | Missense Mutation (SNP) | VAF 162/2004 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- POTEJ | c.204C>A p.C68* | Nonsense Mutation (SNP) | VAF 169/486 reads (35%) | called by muse, mutect2, varscan2
- PPIL3 | c.202G>T p.G68C (on ENST00000392283 / NM_130906.3; = p.G72C on NM_032472.4) | Missense Mutation (SNP) | VAF 71/213 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- PRDM10 | c.1528C>A p.R510= | Splice Region (SNP) | VAF 129/449 reads (29%) | called by muse, mutect2, varscan2
- PRPSAP1 | c.772G>T p.E258* | Nonsense Mutation (SNP) | VAF 252/253 reads (100%) | called by muse, mutect2, varscan2
- PSAT1 | c.903G>C p.M301I | Missense Mutation (SNP) | VAF 216/216 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- PSD4 | c.341C>T p.T114I | Missense Mutation (SNP) | VAF 203/440 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PTGR1 | c.455G>C p.G152A | Missense Mutation (SNP) | VAF 274/274 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PTPRJ | c.2158G>T p.A720S | Missense Mutation (SNP) | VAF 219/219 reads (100%) | SIFT tolerated (0.06); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- PTPRO | c.1616A>T p.Y539F | Missense Mutation (SNP) | VAF 309/309 reads (100%) | SIFT tolerated (0.08); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PTPRO | c.2629C>G p.R877G | Missense Mutation (SNP) | VAF 84/177 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PURG | c.760G>T p.G254* | Nonsense Mutation (SNP) | VAF 167/353 reads (47%) | called by muse, mutect2, varscan2
- QRFPR | c.544C>A p.H182N | Missense Mutation (SNP) | VAF 353/353 reads (100%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- RAB27B | c.153G>T p.V51= | Splice Region (SNP) | VAF 67/130 reads (52%) | called by muse, mutect2, varscan2
- RABGGTA | c.884G>T p.R295L | Missense Mutation (SNP) | VAF 129/367 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- RAD54B | c.448A>T p.K150* | Nonsense Mutation (SNP) | VAF 92/359 reads (26%) | called by muse, varscan2
- RAD54B | c.429dup p.D144* | Frame Shift Ins (INS) | VAF 110/474 reads (23%) | called by pindel, varscan2
- RASGRP1 | c.1665T>G p.C555W | Missense Mutation (SNP) | VAF 283/284 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBM42 | c.806G>A p.G269E | Missense Mutation (SNP) | VAF 279/872 reads (32%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.538); called by muse, mutect2, varscan2
- RTN4 | c.3071G>A p.S1024N (on ENST00000337526 / NM_020532.5; = p.S31N on NM_007008.3) | Missense Mutation (SNP) | VAF 153/302 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RXRB | c.1537A>T p.I513F | Missense Mutation (SNP) | VAF 465/466 reads (100%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RYR2 | c.7331C>A p.T2444K | Missense Mutation (SNP) | VAF 77/276 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SALL3 | c.427C>G p.R143G | Missense Mutation (SNP) | VAF 207/458 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- SAXO1 | c.919G>C p.V307L | Missense Mutation (SNP) | VAF 181/585 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- SCG2 | c.629G>A p.G210E | Missense Mutation (SNP) | VAF 142/289 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- SCN3A | c.1682G>T p.S561I | Missense Mutation (SNP) | VAF 128/243 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SCN7A | c.782G>C p.G261A | Missense Mutation (SNP) | VAF 131/297 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SGCG | c.390del p.M132Wfs*2 | Frame Shift Del (DEL) | VAF 168/230 reads (73%) | called by mutect2, pindel, varscan2
- SHANK1 | c.1667G>T p.G556V | Missense Mutation (SNP) | VAF 444/674 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SHISA9 | c.796C>G p.Q266E | Missense Mutation (SNP) | VAF 201/444 reads (45%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- SHROOM3 | c.4674G>T p.Q1558H | Missense Mutation (SNP) | VAF 294/296 reads (99%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SIAE | c.121G>T p.E41* | Nonsense Mutation (SNP) | VAF 390/556 reads (70%) | called by mutect2, varscan2
- SIGLEC10 | c.2036C>T p.P679L | Missense Mutation (SNP) | VAF 401/581 reads (69%) | SIFT tolerated (0.28); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SIGLEC5 | c.806G>C p.C269S | Missense Mutation (SNP) | VAF 200/667 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC18B1 | c.686G>C p.W229S | Missense Mutation (SNP) | VAF 237/557 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- SLC6A12 | c.1769G>T p.G590V | Missense Mutation (SNP) | VAF 20/468 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2
- SMG7 | c.560A>G p.Q187R | Missense Mutation (SNP) | VAF 166/250 reads (66%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- SNRNP200 | c.1946T>C p.I649T | Missense Mutation (SNP) | VAF 218/468 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- SNTG1 | c.428C>A p.P143H | Missense Mutation (SNP) | VAF 69/206 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SPATA31D1 | c.2430G>T p.M810I | Missense Mutation (SNP) | VAF 238/482 reads (49%) | SIFT tolerated (0.51); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- SPEM3 | c.1924C>A p.P642T | Missense Mutation (SNP) | VAF 305/307 reads (99%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- SPG7 | c.1744G>T p.E582* (on ENST00000268704; = p.E589* on NM_003119.4) | Nonsense Mutation (SNP) | VAF 120/120 reads (100%) | called by muse, mutect2, varscan2
- SPTA1 | c.2589A>T p.G863= | Splice Region (SNP) | VAF 253/376 reads (67%) | called by muse, mutect2, varscan2
- SPTBN4 | c.1300T>A p.F434I | Missense Mutation (SNP) | VAF 125/306 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SSC5D | c.806dup p.G270Rfs*19 | Frame Shift Ins (INS) | VAF 417/805 reads (52%) | called by mutect2, pindel, varscan2
- STAC | c.489G>T p.L163= | Splice Region (SNP) | VAF 144/144 reads (100%) | called by muse, mutect2, varscan2
- SVEP1 | c.9851A>G p.N3284S | Missense Mutation (SNP) | VAF 265/266 reads (100%) | SIFT tolerated (0.16); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- SYNE2 | c.3182G>A p.G1061E | Missense Mutation (SNP) | VAF 99/334 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- SYTL1 | c.231G>T p.K77N | Missense Mutation (SNP) | VAF 369/370 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- TAF1 | c.3002C>T p.S1001F (on ENST00000373790 / NM_138923.4; = p.S1022F on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 157/158 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TBC1D24 | c.1367del p.P456Hfs*3 (on ENST00000646147 / NM_001199107.2; = p.P450Hfs*3 on NM_020705.3) | Frame Shift Del (DEL) | VAF 493/688 reads (72%) | called by mutect2, pindel, varscan2
- TCERG1 | c.630G>T p.Q210H | Missense Mutation (SNP) | VAF 353/361 reads (98%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- TCHHL1 | c.1322G>T p.G441V | Missense Mutation (SNP) | VAF 182/566 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TECRL | c.199G>T p.A67S | Missense Mutation (SNP) | VAF 146/146 reads (100%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- TEKT4 | c.89C>A p.A30D | Missense Mutation (SNP) | VAF 218/445 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- TENM4 | c.1952G>T p.G651V | Missense Mutation (SNP) | VAF 262/406 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by mutect2, varscan2
- TET1 | c.4123G>T p.V1375F | Missense Mutation (SNP) | VAF 148/148 reads (100%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- TEX14 | c.365del p.G122Vfs*9 | Frame Shift Del (DEL) | VAF 336/464 reads (72%) | called by mutect2, pindel, varscan2
- TEX36 | c.45del p.R16Dfs*8 | Frame Shift Del (DEL) | VAF 191/264 reads (72%) | called by mutect2, pindel, varscan2
- THAP9 | c.1120G>T p.D374Y | Missense Mutation (SNP) | VAF 140/279 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TLN1 | c.1975G>T p.D659Y | Missense Mutation (SNP) | VAF 135/497 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- TMEM132D | c.1262G>T p.S421I | Missense Mutation (SNP) | VAF 248/250 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- TMEM67 | c.2164A>T p.S722C | Missense Mutation (SNP) | VAF 229/632 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- TMEM94 | c.1051A>T p.K351* | Nonsense Mutation (SNP) | VAF 306/306 reads (100%) | called by muse, mutect2, varscan2
- TRIM54 | c.375G>T p.M125I | Missense Mutation (SNP) | VAF 123/284 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- TRPM2 | c.4028G>T p.G1343V | Missense Mutation (SNP) | VAF 358/359 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- TSC22D3 | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 170/357 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- TTC25 | c.452A>T p.Q151L | Missense Mutation (SNP) | VAF 231/233 reads (99%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- TTC34 | c.1159G>A p.A387T | Missense Mutation (SNP) | VAF 30/366 reads (8%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.691); called by muse, mutect2
- TTK | c.984G>C p.K328N | Missense Mutation (SNP) | VAF 112/275 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- TTN | c.58515_58516del p.A19506Pfs*19 (on ENST00000591111; = p.A12082Pfs*19 on NM_003319.4) | Frame Shift Del (DEL) | VAF 135/379 reads (36%) | called by pindel, varscan2
- TTN | c.29319T>A p.S9773R (on ENST00000591111; = p.S8846R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 146/303 reads (48%) | PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TTN | c.25780G>C p.D8594H (on ENST00000591111; = p.D7667H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 145/312 reads (46%) | PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- TTN | c.7234C>A p.L2412M (on ENST00000591111; = p.L2366M on NM_003319.4) | Missense Mutation (SNP) | VAF 209/436 reads (48%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TUNAR | c.112G>T p.E38* | Nonsense Mutation (SNP) | VAF 347/514 reads (68%) | called by muse, mutect2, varscan2
- WDFY4 | c.5522C>A p.S1841Y | Missense Mutation (SNP) | VAF 424/424 reads (100%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.592); called by muse, mutect2, varscan2
- WDR75 | c.325G>T p.A109S | Missense Mutation (SNP) | VAF 80/170 reads (47%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- WDR87 | c.1294C>G p.R432G | Missense Mutation (SNP) | VAF 140/338 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- XIAP | c.166G>A p.G56S | Missense Mutation (SNP) | VAF 20/552 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- XIRP2 | c.9250C>A p.Q3084K (on ENST00000628543; = p.Q3259K on NM_152381.6) | Missense Mutation (SNP) | VAF 163/361 reads (45%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- ZEB1 | c.1816C>A p.P606T | Missense Mutation (SNP) | VAF 161/465 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZIK1 | c.6_33+2del p.X2_splice | Splice Site (DEL) | VAF 69/473 reads (15%) | called by mutect2, pindel, varscan2
- ZNF148 | c.2384_2385insC p.*795Yfs*9 | Frame Shift Ins (INS) | VAF 40/291 reads (14%) | called by pindel, varscan2*
- ZNF263 | c.974del p.R325Qfs*69 | Frame Shift Del (DEL) | VAF 317/439 reads (72%) | called by mutect2, pindel, varscan2
- ZNF519 | c.1120A>G p.K374E | Missense Mutation (SNP) | VAF 211/422 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- ABCB1 | c.270A>T p.S90= | Silent (SNP) | VAF 311/311 reads (100%) | called by muse, mutect2, varscan2
- ADAM19 | c.1767G>C p.A589= | Silent (SNP) | VAF 213/213 reads (100%) | catalogued as COSV57438716; called by muse, mutect2, varscan2
- ADAMTSL2 | c.2490G>A p.Q830= | Silent (SNP) | VAF 489/489 reads (100%) | called by muse, mutect2, varscan2
- ARMC9 | c.867G>A p.T289= | Silent (SNP) | VAF 129/314 reads (41%) | catalogued as rs768528669; called by muse, mutect2, varscan2
- ARMH4 | c.1524T>A p.P508= | Silent (SNP) | VAF 159/522 reads (30%) | called by muse, mutect2, varscan2
- ARMH4 | c.1002A>G p.E334= | Silent (SNP) | VAF 159/471 reads (34%) | called by muse, mutect2, varscan2
- ATP1A3 | c.2568C>A p.A856= (on ENST00000545399 / NM_001256214.2; = p.A843= on NM_152296.5) | Silent (SNP) | VAF 132/294 reads (45%) | called by muse, varscan2
- AUTS2 | c.2661G>A p.K887= | Silent (SNP) | VAF 17/629 reads (3%) | catalogued as rs917489133, COSV100719072; called by muse, mutect2
- BEST3 | c.1497G>T p.L499= | Silent (SNP) | VAF 363/363 reads (100%) | called by muse, mutect2, varscan2
- BIN1 | c.1350G>T p.T450= | Silent (SNP) | VAF 187/422 reads (44%) | called by muse, mutect2, varscan2
- BIRC7 | c.522G>T p.L174= | Silent (SNP) | VAF 189/552 reads (34%) | called by muse, mutect2, varscan2
- BPI | c.807C>T p.P269= (on ENST00000262865; = p.P265= on NM_001725.3) | Silent (SNP) | VAF 135/500 reads (27%) | catalogued as COSV53403742; called by muse, mutect2, varscan2
- BRDT | c.2340T>C p.D780= | Silent (SNP) | VAF 290/290 reads (100%) | catalogued as rs1253273449; called by muse, mutect2, varscan2
- C1GALT1C1L | c.30T>C p.F10= | Silent (SNP) | VAF 97/206 reads (47%) | called by muse, mutect2, varscan2
- C7orf26 | c.378A>T p.R126= | Silent (SNP) | VAF 11/355 reads (3%) | called by muse, mutect2
- C9orf72 | c.1212C>A p.V404= | Silent (SNP) | VAF 164/253 reads (65%) | called by muse, mutect2, varscan2
- CACNA1A | c.3810G>T p.V1270= | Silent (SNP) | VAF 110/450 reads (24%) | called by muse, mutect2, varscan2
- CCDC178 | c.1866G>T p.V622= | Silent (SNP) | VAF 20/92 reads (22%) | called by muse, varscan2
- CCKAR | c.489T>A p.A163= | Silent (SNP) | VAF 268/268 reads (100%) | called by muse, mutect2, varscan2
- CD1A | c.168C>A p.T56= | Silent (SNP) | VAF 178/621 reads (29%) | catalogued as rs1022289158; called by muse, mutect2, varscan2
- CDH4 | c.438G>T p.P146= | Silent (SNP) | VAF 408/647 reads (63%) | catalogued as COSV100849383; called by muse, mutect2, varscan2
- CFAP46 | c.1750C>T p.L584= | Silent (SNP) | VAF 133/133 reads (100%) | called by muse, mutect2, varscan2
- CFAP47 | c.2115C>A p.T705= | Silent (SNP) | VAF 167/167 reads (100%) | catalogued as COSV99934357; called by muse, mutect2, varscan2
- CHI3L1 | c.432G>A p.R144= | Silent (SNP) | VAF 143/436 reads (33%) | catalogued as COSV55137528; called by muse, mutect2, varscan2
- CLASP2 | c.2259T>C p.I753= | Silent (SNP) | VAF 179/179 reads (100%) | called by muse, mutect2, varscan2
- CLRN1 | c.460T>C p.L154= (on ENST00000327047 / NM_174878.3; = p.L78= on NM_052995.2) | Silent (SNP) | VAF 110/567 reads (19%) | called by muse, mutect2, varscan2
- CPB2 | c.849T>G p.P283= | Silent (SNP) | VAF 126/267 reads (47%) | called by muse, mutect2, varscan2
- CSPP1 | c.867G>T p.V289= (on ENST00000676605; = p.V248= on NM_024790.6) | Silent (SNP) | VAF 120/426 reads (28%) | called by muse, mutect2, varscan2
- DNAH9 | c.2556C>A p.L852= | Silent (SNP) | VAF 208/208 reads (100%) | called by muse, mutect2, varscan2
- DYTN | c.1389C>A p.T463= | Silent (SNP) | VAF 184/346 reads (53%) | called by muse, mutect2, varscan2
- EMILIN2 | c.405G>A p.R135= | Silent (SNP) | VAF 179/425 reads (42%) | catalogued as COSV54421808; called by muse, mutect2
- ENAM | c.186A>G p.Q62= | Silent (SNP) | VAF 208/209 reads (100%) | catalogued as rs375068287; called by muse, mutect2, varscan2
- ERVV-2 | c.1041C>A p.V347= | Silent (SNP) | VAF 139/545 reads (26%) | called by muse, mutect2, varscan2
- ESRRG | c.390G>T p.V130= | Silent (SNP) | VAF 171/573 reads (30%) | called by muse, mutect2, varscan2
- FFAR3 | c.553C>A p.R185= | Silent (SNP) | VAF 397/1352 reads (29%) | catalogued as rs150489647, COSV59909432; called by muse, mutect2, varscan2
- FIGN | c.30A>T p.T10= | Silent (SNP) | VAF 116/266 reads (44%) | called by muse, mutect2, varscan2
- GALNT4 | c.18T>A p.T6= | Silent (SNP) | VAF 249/250 reads (100%) | called by muse, mutect2, varscan2
- GAS8 | c.1194C>T p.A398= | Silent (SNP) | VAF 116/116 reads (100%) | called by muse, mutect2, varscan2
- GPAT2 | c.1869C>A p.I623= | Silent (SNP) | VAF 166/322 reads (52%) | called by muse, mutect2, varscan2
- GZMM | c.621G>T p.S207= | Silent (SNP) | VAF 440/441 reads (100%) | called by muse, mutect2, varscan2
- HIGD1B | c.193C>A p.R65= | Silent (SNP) | VAF 334/334 reads (100%) | catalogued as COSV99494033; called by muse, mutect2, varscan2
- HSPG2 | c.6279C>T p.P2093= | Silent (SNP) | VAF 146/303 reads (48%) | called by muse, mutect2, varscan2
- IL36RN | c.54G>T p.V18= | Silent (SNP) | VAF 154/359 reads (43%) | called by muse, mutect2, varscan2
- INTS2 | c.570C>G p.S190= | Silent (SNP) | VAF 142/142 reads (100%) | called by muse, mutect2, varscan2
- IRS2 | c.777G>T p.V259= | Silent (SNP) | VAF 210/211 reads (100%) | catalogued as COSV101019125; called by muse, mutect2, varscan2
- KANK2 | c.786G>C p.L262= | Silent (SNP) | VAF 698/698 reads (100%) | called by muse, mutect2, varscan2
- KCNV2 | c.1248C>G p.L416= | Silent (SNP) | VAF 226/733 reads (31%) | called by muse, mutect2, varscan2
- KDR | c.2166C>A p.L722= | Silent (SNP) | VAF 265/615 reads (43%) | called by muse, mutect2, varscan2
- KLHDC7A | c.2268G>T p.P756= | Silent (SNP) | VAF 385/386 reads (100%) | catalogued as rs762203639; called by muse, mutect2, varscan2
- LAMA1 | c.5538C>A p.A1846= | Silent (SNP) | VAF 126/270 reads (47%) | called by muse, mutect2, varscan2
- LCT | c.3759G>T p.T1253= | Silent (SNP) | VAF 191/394 reads (48%) | catalogued as COSV51557058; called by muse, mutect2, varscan2
- LRFN5 | c.403C>T p.L135= | Silent (SNP) | VAF 289/472 reads (61%) | called by muse, mutect2, varscan2
- LYPD4 | c.42T>A p.L14= | Silent (SNP) | VAF 190/379 reads (50%) | called by muse, mutect2, varscan2
- MSH3 | c.1722G>C p.R574= | Silent (SNP) | VAF 107/107 reads (100%) | called by muse, mutect2, varscan2
- MTO1 | c.741C>T p.S247= | Silent (SNP) | VAF 339/531 reads (64%) | called by muse, mutect2, varscan2
- MYO7A | c.3568C>A p.R1190= | Silent (SNP) | VAF 225/665 reads (34%) | called by muse, mutect2, varscan2
- NBPF4 | c.1869C>T p.S623= | Silent (SNP) | VAF 10/10 reads (100%) | catalogued as rs2582071; called by muse, varscan2
- NDUFS1 | c.471G>A p.K157= | Silent (SNP) | VAF 103/258 reads (40%) | catalogued as rs143938551; called by muse, mutect2, varscan2
- NEK8 | c.1101T>C p.S367= | Silent (SNP) | VAF 324/324 reads (100%) | called by muse, mutect2, varscan2
- NLRP10 | c.477G>A p.G159= | Silent (SNP) | VAF 631/631 reads (100%) | called by muse, mutect2, varscan2
- NNMT | c.531C>T p.C177= | Silent (SNP) | VAF 658/888 reads (74%) | called by muse, mutect2, varscan2
- NPY2R | c.570G>T p.S190= | Silent (SNP) | VAF 422/422 reads (100%) | catalogued as COSV100279426; called by muse, mutect2, varscan2
- OCLN | c.567C>T p.A189= | Silent (SNP) | VAF 171/171 reads (100%) | called by muse, mutect2, varscan2
- OR2T1 | c.288C>T p.C96= | Silent (SNP) | VAF 540/877 reads (62%) | catalogued as COSV63541107; called by muse, mutect2, varscan2
- OR2T2 | c.183C>T p.Y61= | Silent (SNP) | VAF 249/1615 reads (15%) | called by muse, mutect2, varscan2
- OR52L1 | c.159C>T p.Y53= | Silent (SNP) | VAF 416/416 reads (100%) | called by muse, mutect2, varscan2
- OR8B3 | c.474C>A p.A158= | Silent (SNP) | VAF 419/701 reads (60%) | called by muse, mutect2, varscan2
- OR9G1 | c.789T>C p.S263= | Silent (SNP) | VAF 183/825 reads (22%) | called by muse, mutect2, varscan2
- OTOL1 | c.723G>A p.K241= | Silent (SNP) | VAF 211/632 reads (33%) | called by muse, mutect2, varscan2
- PCDHA1 | c.1803G>A p.S601= | Silent (SNP) | VAF 171/172 reads (99%) | catalogued as rs555223653, COSV65374508; called by muse, mutect2, varscan2
- PDE4DIP | c.543C>T p.S181= | Silent (SNP) | VAF 74/286 reads (26%) | called by muse, varscan2
- PDGFRB | c.3099T>A p.A1033= | Silent (SNP) | VAF 144/144 reads (100%) | called by muse, mutect2, varscan2
- PEAK1 | c.2988T>C p.A996= | Silent (SNP) | VAF 164/342 reads (48%) | called by muse, mutect2, varscan2
- PIK3R6 | c.849C>A p.P283= | Silent (SNP) | VAF 312/312 reads (100%) | called by muse, mutect2, varscan2
- PLD1 | c.231C>T p.S77= | Silent (SNP) | VAF 135/716 reads (19%) | catalogued as rs999483206, COSV100577495, COSV60574948; called by muse, mutect2, varscan2
- PLXNA1 | c.2205A>G p.P735= | Silent (SNP) | VAF 509/786 reads (65%) | called by muse, mutect2, varscan2
- POTEG | c.405C>A p.V135= | Silent (SNP) | VAF 258/2632 reads (10%) | catalogued as COSV101611995, COSV101612038; called by muse, mutect2
- PRDM13 | c.1131G>T p.P377= | Silent (SNP) | VAF 526/532 reads (99%) | called by muse, varscan2
- PREX2 | c.429G>T p.R143= | Silent (SNP) | VAF 111/190 reads (58%) | called by muse, mutect2, varscan2
- PTCD1 | c.531G>T p.T177= | Silent (SNP) | VAF 652/653 reads (100%) | catalogued as rs777870987, COSV52862213; called by muse, mutect2, varscan2
- RFX6 | c.888A>G p.Q296= | Silent (SNP) | VAF 178/179 reads (99%) | called by muse, mutect2, varscan2
- RIN1 | c.474G>T p.P158= | Silent (SNP) | VAF 114/416 reads (27%) | called by muse, mutect2, varscan2
- RSAD2 | c.408G>T p.L136= | Silent (SNP) | VAF 158/360 reads (44%) | called by muse, mutect2, varscan2
- SAMD3 | c.123G>T p.R41= | Silent (SNP) | VAF 282/579 reads (49%) | called by muse, mutect2, varscan2
- SCAP | c.765G>C p.L255= | Silent (SNP) | VAF 178/178 reads (100%) | catalogued as COSV55559810; called by muse, mutect2, varscan2
- SDK2 | c.6321G>T p.S2107= | Silent (SNP) | VAF 396/396 reads (100%) | catalogued as COSV101168785; called by muse, varscan2
- SERPINB8 | c.654G>T p.L218= | Silent (SNP) | VAF 194/393 reads (49%) | called by muse, mutect2, varscan2
- SERPINE3 | c.1194G>A p.R398= | Silent (SNP) | VAF 251/251 reads (100%) | catalogued as COSV60877500; called by muse, mutect2, varscan2
- SEZ6L2 | c.1998G>A p.T666= (on ENST00000308713 / NM_001114099.3; = p.T596= on NM_012410.4) | Silent (SNP) | VAF 240/494 reads (49%) | called by muse, mutect2, varscan2
- SNTA1 | c.162C>T p.G54= | Silent (SNP) | VAF 228/651 reads (35%) | catalogued as rs544127915; called by muse, mutect2, varscan2
- SOHLH1 | c.957C>A p.G319= | Silent (SNP) | VAF 385/385 reads (100%) | catalogued as COSV53684646; called by muse, mutect2, varscan2
- SORL1 | c.2346G>A p.L782= | Silent (SNP) | VAF 544/752 reads (72%) | called by muse, mutect2, varscan2
- SP1 | c.2178G>T p.L726= (on ENST00000327443 / NM_138473.3; = p.L719= on NM_003109.1) | Silent (SNP) | VAF 237/454 reads (52%) | called by muse, mutect2, varscan2
- SPAST | c.663C>A p.R221= | Silent (SNP) | VAF 105/216 reads (49%) | called by muse, mutect2, varscan2
- SPATA24 | c.69G>A p.R23= | Silent (SNP) | VAF 127/127 reads (100%) | called by muse, mutect2, varscan2
- SPATA4 | c.882T>A p.A294= | Silent (SNP) | VAF 237/238 reads (100%) | called by muse, mutect2, varscan2
- SPTA1 | c.5940C>T p.F1980= | Silent (SNP) | VAF 209/346 reads (60%) | called by muse, mutect2, varscan2
- SPTBN4 | c.7683G>C p.G2561= | Silent (SNP) | VAF 122/260 reads (47%) | called by muse, mutect2, varscan2
- SSU72P5 | c.390C>A p.T130= | Silent (SNP) | VAF 142/391 reads (36%) | called by muse, mutect2, varscan2
- SYNE1 | c.25284A>G p.A8428= (on ENST00000367255 / NM_182961.4; = p.A8380= on NM_033071.3) | Silent (SNP) | VAF 296/628 reads (47%) | called by muse, mutect2, varscan2
- TAAR9 | c.117T>C p.L39= | Silent (SNP) | VAF 374/794 reads (47%) | called by muse, mutect2
- TAF4 | c.1272G>T p.R424= | Silent (SNP) | VAF 316/977 reads (32%) | called by muse, mutect2, varscan2
- TCP10L2 | c.18C>T p.L6= | Silent (SNP) | VAF 267/588 reads (45%) | catalogued as rs371272516; called by muse, mutect2, varscan2
- TCTN1 | c.658C>T p.L220= | Silent (SNP) | VAF 213/213 reads (100%) | called by muse, mutect2, varscan2
- THSD7A | c.2295G>C p.L765= | Silent (SNP) | VAF 17/260 reads (7%) | called by muse, mutect2
- TMEM121 | c.327G>A p.A109= | Silent (SNP) | VAF 22/878 reads (3%) | catalogued as rs368412724; called by muse, mutect2
- TOX | c.1428C>A p.I476= | Silent (SNP) | VAF 128/282 reads (45%) | called by muse, mutect2, varscan2
- TOX2 | c.1377C>T p.S459= (on ENST00000358131 / NM_001098798.2; = p.S435= on NM_032883.3) | Silent (SNP) | VAF 170/507 reads (34%) | catalogued as rs372255529; called by muse, mutect2, varscan2
- TRAF3 | c.717C>T p.C239= | Silent (SNP) | VAF 248/370 reads (67%) | catalogued as COSV61026999; called by muse, mutect2, varscan2
- TTYH3 | c.576G>C p.A192= | Silent (SNP) | VAF 344/345 reads (100%) | catalogued as COSV99350138; called by muse, mutect2, varscan2
- UNC13B | c.4524T>C p.Y1508= | Silent (SNP) | VAF 164/465 reads (35%) | called by muse, mutect2, varscan2
- ZFHX4 | c.1113T>C p.N371= | Silent (SNP) | VAF 355/536 reads (66%) | catalogued as COSV50529481; called by muse, mutect2, varscan2
- ZNF292 | c.480G>T p.V160= | Silent (SNP) | VAF 244/547 reads (45%) | catalogued as rs944941809; called by muse, mutect2, varscan2
- ZNF77 | c.942C>T p.H314= | Silent (SNP) | VAF 540/540 reads (100%) | catalogued as rs375827028; called by muse, mutect2, varscan2
- AC126468.1 | n.207G>A | RNA (SNP) | VAF 138/292 reads (47%) | called by muse, mutect2, varscan2
- ADD1 | c.1605+822A>T | Intron (SNP) | VAF 90/91 reads (99%) | called by muse, mutect2, varscan2
- C9orf92 | n.83+23187C>T | Intron (SNP) | VAF 75/300 reads (25%) | called by muse, mutect2, varscan2
- COA8 | c.-10G>T | 5'UTR (SNP) | VAF 202/646 reads (31%) | called by muse, mutect2
- DCHS2 | n.6387G>T | RNA (SNP) | VAF 306/307 reads (100%) | called by muse, mutect2, varscan2
- DNAH14 | c.1032+6558C>A | Intron (SNP) | VAF 22/107 reads (21%) | called by muse, mutect2, varscan2
- FAM169B | n.271G>T | RNA (SNP) | VAF 458/459 reads (100%) | called by muse, mutect2, varscan2
- FUT9 | c.*7876G>A | 3'UTR (SNP) | VAF 136/373 reads (36%) | called by muse, mutect2, varscan2
- GHRHR | c.269-38G>T | Intron (SNP) | VAF 523/525 reads (100%) | catalogued as rs779764987; called by muse, mutect2, varscan2
- GLI4 | c.223+255G>T | Intron (SNP) | VAF 459/1234 reads (37%) | called by muse, mutect2, varscan2
- ICOSLG | c.898+331G>T | Intron (SNP) | VAF 511/516 reads (99%) | called by muse, mutect2, varscan2
- IGFN1 | c.1241+2070G>T | Intron (SNP) | VAF 331/514 reads (64%) | catalogued as COSV55181604; called by muse, mutect2, varscan2
- IGFN1 | c.1242-2779G>T | Intron (SNP) | VAF 454/779 reads (58%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+21213dup | Intron (INS) | VAF 324/452 reads (72%) | called by mutect2, pindel, varscan2
- KCNQ2 | c.1763+1606C>T | Intron (SNP) | VAF 171/543 reads (31%) | called by muse, mutect2, varscan2
- KIR3DX1 | n.141T>A | RNA (SNP) | VAF 133/426 reads (31%) | called by muse, mutect2, varscan2
- MEGF11 | c.2711-2986T>C | Intron (SNP) | VAF 124/231 reads (54%) | called by muse, mutect2, varscan2
- MEX3B | c.256+69A>T | Intron (SNP) | VAF 815/820 reads (99%) | called by muse, mutect2, varscan2
- MYC | c.-24G>T | 5'UTR (SNP) | VAF 486/854 reads (57%) | catalogued as COSV104388229, COSV52373180; called by muse, mutect2, varscan2
- NAT1 | c.-85-2472G>T | Intron (SNP) | VAF 187/382 reads (49%) | called by muse, mutect2, varscan2
- PRSS40A | n.142-2213C>A | Intron (SNP) | VAF 253/1081 reads (23%) | catalogued as rs996090755; called by muse, mutect2, varscan2
- SLC22A17 | n.279G>T | RNA (SNP) | VAF 510/840 reads (61%) | called by muse, mutect2, varscan2
- SLC9A9 | c.*825T>A | 3'UTR (SNP) | VAF 503/638 reads (79%) | called by muse, mutect2, varscan2
- TMEM123 | c.*196G>C | 3'UTR (SNP) | VAF 114/488 reads (23%) | called by mutect2, varscan2
- TTLL9 | c.70-3144G>T | Intron (SNP) | VAF 103/381 reads (27%) | called by muse, mutect2, varscan2
- TTLL9 | c.70-3143G>T | Intron (SNP) | VAF 105/380 reads (28%) | catalogued as rs1277895333; called by muse, mutect2, varscan2
- UVSSA | c.*9628G>T | 3'UTR (SNP) | VAF 224/268 reads (84%) | catalogued as rs1186524488; called by mutect2, varscan2
- VIL1 | c.1102+70C>A | Intron (SNP) | VAF 192/436 reads (44%) | called by muse, mutect2, varscan2
- VIL1 | c.1102+71C>A | Intron (SNP) | VAF 194/435 reads (45%) | catalogued as rs763384912; called by muse, mutect2, varscan2
- WSCD2 | c.1346-3454C>G | Intron (SNP) | VAF 332/332 reads (100%) | called by muse, mutect2, varscan2
- ZNF783 | c.802+3048G>C | Intron (SNP) | VAF 632/632 reads (100%) | called by muse, mutect2, varscan2
